Somatic mutation profile of tumor specimen ALCH-B3H6-TTP1-A (aliquot ALCH-B3H6-TTP1-A-1-0-D-A78R-36) from ALCHEMIST case ALCH-B3H6, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 59.7 years (21,817 days).
Specimen ALCH-B3H6-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9aa3c71f-fe20-4a37-8798-5df57f7e3238.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B3H6-NB1-A (Blood Derived Normal), aliquot ALCH-B3H6-NB1-A-1-0-D-A78R-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dfc60bed-cf04-48bb-8c94-3b4abcd25aa8

The open-access MAF lists 19 somatic variants for this specimen: 14 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Silent 4, Splice Site 1, RNA 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NPBWR2 | c.970C>T p.R324W | Missense Mutation (SNP) | VAF 7/92 reads (8%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.868); catalogued as rs199972319; called by muse, mutect2
- PDE6B | c.460G>A p.V154M | Missense Mutation (SNP) | VAF 20/228 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs756889736; ClinVar: uncertain significance; called by muse, mutect2
- RAPH1 | c.344C>T p.T115M | Missense Mutation (SNP) | VAF 15/143 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.072); catalogued as rs142789651; called by muse, mutect2
- SLC4A3 | c.3308G>A p.R1103H | Missense Mutation (SNP) | VAF 16/164 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs756383532; called by muse, mutect2
- STARD9 | c.3499C>T p.R1167C | Missense Mutation (SNP) | VAF 24/296 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as rs564320988; called by muse, mutect2
- APOB | c.10651G>T p.A3551S | Missense Mutation (SNP) | VAF 16/192 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.121); called by muse, mutect2
- CPSF6 | c.310_311insA p.L104Yfs*5 | Frame Shift Ins (INS) | VAF 10/99 reads (10%) | called by mutect2, pindel
- EZR | c.13-1G>T p.X5_splice | Splice Site (SNP) | VAF 17/166 reads (10%) | called by muse, mutect2, varscan2
- KDM5A | c.1300G>A p.E434K | Missense Mutation (SNP) | VAF 22/334 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.089); called by muse, mutect2
- NAB1 | c.364G>A p.E122K | Missense Mutation (SNP) | VAF 49/744 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.015); called by muse, mutect2
- OR14I1 | c.538C>T p.P180S | Missense Mutation (SNP) | VAF 10/134 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.764); called by muse, mutect2
- PAWR | c.82G>C p.E28Q | Missense Mutation (SNP) | VAF 27/384 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- RAB2A | c.212T>G p.I71S | Missense Mutation (SNP) | VAF 10/140 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SASH1 | c.1887A>C p.K629N | Missense Mutation (SNP) | VAF 16/318 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.632); called by muse, mutect2
- CD248 | c.384C>T p.A128= | Silent (SNP) | VAF 12/218 reads (6%) | called by muse, mutect2
- ERICH3 | c.2487G>A p.R829= | Silent (SNP) | VAF 9/90 reads (10%) | catalogued as rs374973689; called by muse, mutect2
- ESPNL | c.1230G>A p.A410= | Silent (SNP) | VAF 24/302 reads (8%) | catalogued as COSV58036734; called by muse, mutect2
- PHACTR3 | c.1260C>T p.N420= | Silent (SNP) | VAF 34/444 reads (8%) | catalogued as rs770049446; called by muse, mutect2
- LINC00602 | n.39A>T | RNA (SNP) | VAF 5/79 reads (6%) | called by muse, mutect2
